Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A13Z, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A13Z-01A (Primary Tumor).

[page 1 of 2]
100-0-3
Infiltrating Duct Carcinoma, NOS
8500/3
Site: breast, NOS 0509
11/22/10

page 1 / 2

Department of Cancer Pathology

copy No. :

Examination: Histopathological examination

Examination No.:

Patient# PESEL: Age: Gender: F

Material: **Multiple organ resection – right breast**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: **up to 8 working days**

Clinical diagnosis: **Bifocal cancer of the right breast.** ✓

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors in neoplastic cell nuclei not found. Progesterone receptors in neoplastic cell nuclei not found. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

Examination performed on

Results of immunohistochemical examination:

Assessment of the receptor status for the other tumour (prep. IH) Estrogen receptors found in 10-75% of neoplastic cell nuclei. Progesterone receptors found in 10-75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

Examination performed on:

Macroscopic description:

✓ **Right breast, sized 22.5 x 17 x 4 cm, removed along with axillary tissues sized 9 x 6 x 7 cm and a skin flap of 20 x 9 cm. Weight 600 g.**

Tumour sized 4.5 x 2.5 x 2.3 cm on the border of the lower quadrants, placed 6.7 cm from the lower edge, 1.1 cm from the base and 1.6 cm from the skin.

The other tumour, sized 1.3 x 1.2 x 1.2, found 3 cm from the first one (margins: lower area 1.7 cm, base 1.4 cm, skin 0.9 cm).

Lymph nodes of 0.4 cm in length, metastatic.

Microscopic description: ✓

Tumour 1 - Carcinoma ductale invasivum cum necrosi NHG3 (3 + 3 + 3/21 mitoses/10 HPF - visual area 0.55 mm). Focuses of carcinoma ductale in situ DCIS found within and outside the tumour (solid and flat type, with high nuclear atypia and comedo necrosis < 10% of the tumour). Cancerisatio lobulorum.

Tumour 2 - Carcinoma invasivum mixtum partim ductale, partim papilläre, partim cribrosum

Site Length		
Investigator		
Reviewed		

Signature: [Signature] Date: [Date]

[page 2 of 2]
Patient: PESEL

Gender: F

Examination performed on:

NGH2 (2 + 2 + 2/9 mitoses/ 10 HPF/ visual area diameter 0.55 mm).

Carcinoma intraductale ductuum mamillae.

Glandular tissue showing mastopathia fibrosa et cystica.

AXILLARY LYMPH NODES:

Metastases carcinomatosae in lymphonodis (No IX/XI).

Infiltratio capsulae lymphonodorum.

Emboliae carcinomatosae vasorum.

Examination result:

Carcinoma invasivum bifocale.

Tumour 1 - Carcinoma ductale inyasium NHG3, pT2.

Tumour 2 - Carcinoma invasivum mixtum NHG2, pT1c. (NHG3, pT2, pN2a).

DUCTAL INVASIVE CARCINOMA

re validated by: .

Source: NCI Genomic Data Commons file 5b966383-6041-4ce4-b287-637da2540c40 (TCGA-D8-A13Z.8EFA6C19-2FA1-4F23-AF7B-15681E8E930A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).